Somatic mutation profile of tumor specimen TCGA-AN-A0FY-01A (aliquot TCGA-AN-A0FY-01A-11W-A050-09) from TCGA case TCGA-AN-A0FY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.7 years (20,347 days).
Specimen TCGA-AN-A0FY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbe0620c-dabe-48c9-988c-b939b1871e8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FY-10A (Blood Derived Normal), aliquot TCGA-AN-A0FY-10A-01D-A047-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50feb181-5896-4834-978d-ce448d60b6d5

The open-access MAF lists 53 somatic variants for this specimen: 48 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 4, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 16/128 reads (13%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 84/124 reads (68%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 139/165 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMCX5 | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55767774; called by muse, mutect2, varscan2
- ASIC3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs765427661, COSV52506439; called by muse, mutect2, varscan2
- C1QTNF9 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs557592254, COSV59658470; called by muse, mutect2
- C1QTNF9B | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs557541660, COSV65944678; called by muse, mutect2, varscan2
- CELSR3 | c.901C>G p.R301G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV50857295, COSV99374869; called by muse, mutect2
- CEP250 | c.6449G>A p.R2150Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs759294916, COSV61173572; called by muse, mutect2, varscan2
- CNGA4 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1232698586, COSV66007186; called by muse, mutect2, varscan2
- COL9A1 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs1270419347, COSV57894325; called by muse, mutect2, varscan2
- CRNKL1 | c.434T>G p.F145C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV55649271; called by muse, mutect2, varscan2
- DMD | c.10683G>T p.E3561D | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374369906, COSV100629160; called by muse, mutect2, varscan2
- DTNB | c.1654T>C p.S552P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as rs780542534, COSV56485453; called by muse, mutect2, varscan2
- ELMO1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs778770532, COSV60302130, COSV60317391; called by muse, mutect2, varscan2
- GAD1 | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60154430; called by muse, mutect2, varscan2
- GAREM1 | c.2254G>A p.E752K (on ENST00000269209 / NM_001242409.2; = p.E751K on NM_022751.3) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as COSV52516543; called by muse, mutect2, varscan2
- GPC6 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV65540389; called by muse, mutect2, varscan2
- GPR162 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781871717, COSV50596748; called by muse, mutect2, varscan2
- GPR55 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1485930939, COSV101235923; called by muse, mutect2
- HEPH | c.2721C>G p.I907M (on ENST00000343002; = p.I640M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/424 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.396); catalogued as COSV100294612, COSV57973389; called by muse, mutect2, varscan2
- KIAA0100 | c.2881C>G p.R961G | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs769233124, COSV66496829; called by muse, mutect2, varscan2
- LAMA4 | c.1060G>A p.E354K (on ENST00000230538 / NM_001105206.3; = p.E347K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/509 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV100039379; called by muse, mutect2
- LCT | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51558472; called by muse, mutect2, varscan2
- LRFN3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150362087; called by muse, mutect2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 24/109 reads (22%) | catalogued as rs777328830; called by mutect2, varscan2
- MUC7 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 89/583 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV59220336; called by muse, mutect2, varscan2
- MYO9A | c.5761C>T p.R1921W | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs144500644; called by muse, mutect2, varscan2
- NBAS | c.6094T>A p.S2032T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV55739417; called by muse, mutect2, varscan2
- NFRKB | c.673C>T p.R225C (on ENST00000446488 / NM_001143835.2; = p.R250C on NM_006165.3) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs753017024, COSV58760817; called by muse, mutect2, varscan2
- NOS1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1451276089, COSV57610696; called by muse, mutect2, varscan2
- NRXN1 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.037); catalogued as COSV58446057, COSV58497815; called by muse, mutect2, varscan2
- OR13C8 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 206/370 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771734811, COSV58610720; called by muse, mutect2, varscan2
- PCED1B | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770009860, COSV71395439; called by muse, mutect2, varscan2
- PLCG1 | c.3727C>T p.R1243* (on ENST00000373271 / NM_182811.2; = p.R1244* on NM_002660.3) | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs756437887, COSV54819289; called by muse, mutect2, varscan2
- PRDM13 | c.50G>C p.C17S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as COSV100980580, COSV65030844; called by muse, mutect2
- RNF113B | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99940402; called by muse, mutect2
- RREB1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV58566527; called by muse, mutect2, varscan2
- SFMBT1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV56257835; called by muse, mutect2, varscan2
- SH2B1 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59467656; called by muse, mutect2, varscan2
- SIMC1 | c.757C>T p.R253W (on ENST00000443967 / NM_001308196.1; = p.R272W on NM_001308195.2) | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as rs756201624, COSV57904129; called by muse, mutect2, varscan2
- TATDN1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs970566327, COSV52682542; called by muse, mutect2, varscan2
- TEKT2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52882317; called by muse, varscan2
- TTC22 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs753225414, COSV64882093; called by muse, mutect2, varscan2
- ZNF33A | c.443T>C p.F148S (on ENST00000458705 / NM_006974.3; = p.F149S on NM_006954.2) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56728143; called by muse, mutect2, varscan2
- ZNF501 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV68516787; called by muse, mutect2, varscan2
- PER3 | c.1014_1021del p.P339Ifs*34 | Frame Shift Del (DEL) | VAF 27/191 reads (14%) | called by mutect2, pindel, varscan2
- SUOX | c.643_645del p.F215del | In Frame Del (DEL) | VAF 26/132 reads (20%) | called by pindel, varscan2
- ADAMTS3 | c.3114C>T p.S1038= | Silent (SNP) | VAF 70/157 reads (45%) | catalogued as rs1229467629, COSV54404298; called by muse, mutect2, varscan2
- BTBD6 | c.981G>A p.L327= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100527741; called by muse, mutect2
- KAT6B | c.3018A>G p.K1006= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as CD119252, COSV99768999; called by muse, mutect2, varscan2
- QSOX2 | c.861G>A p.K287= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV62395525; called by muse, mutect2, varscan2
- GSK3B | c.910-3009A>C | Intron (SNP) | VAF 61/251 reads (24%) | catalogued as COSV51783898; called by muse, mutect2, varscan2
